Surgical pathology report (de-identified scan), TCGA case TCGA-KN-8424, project TCGA-KICH (Kidney Chromophobe), tissue source site Harvard, specimen TCGA-KN-8424-01A (Primary Tumor).

[page 1 of 4]
[REDACTED]

Type: Surgical Pathology

Specimen Type: Kidney, partial or total resection

Procedure Date: [REDACTED]

Ordering Provider: [REDACTED]

[REDACTED]

***** Addended Report *****

[REDACTED]

PATHOLOGIC DIAGNOSIS:

RIGHT KIDNEY, NEPHRECTOMY (573 gm):

RENAL CELL CARCINOMA, chromophobe variant (6.6 cm), Fuhrman nuclear grade 2-3/4
(see NOTE).

Tumor is confined to the kidney.

Resection margins are negative for tumor.

Vascular and ureteral margins of resection are negative for tumor.

No lymphovascular invasion is seen.

Immunohistochemistry performed at [REDACTED] demonstrates the following staining
profile in tumor cells:

Negative - TFE3

AJCC (6th Edition): T1b NX MX.

Special stains to assess adjacent renal parenchyma will be issued as an
addendum.

[page 2 of 4]
NOTE: Cytogenetic findings confirm the above diagnosis. See cytogenetics report

CLINICAL DATA:

History: [REDACTED] with multiple sclerosis. Workup for sciatica found large R renal mass.

Operation: Hand-assisted laparoscopic nephrectomy.

Operative Findings: Large right renal mass.

Clinical Diagnosis: Renal cell CA mass.

TISSUE SUBMITTED:

#1 Right kidney [REDACTED]

GROSS DESCRIPTION:

The specimen is received fresh, labeled with the patient's name, unit number, and "1. Right kidney", and consists of 573 gm right nephrectomy specimen (16 x 11 x 8 cm), including a kidney (15 x 7.5 x 6.3 cm) with attached perirenal adipose (up to 6.0 cm). A 2.2 cm renal artery (diameter 0.5 cm), a 1.3 cm renal vein (diameter 0.9 cm), and a 8.5 cm ureter (0.5 cm) are present at the hilum and are grossly unremarkable. Gerota's fascia has been previously partially inked black. The specimen contains a well-circumscribed, tan/yellow, hemorrhagic mass (6.6 x 6.3 x 5.8 cm), which expands to but does not grossly invade the renal capsule at the lower pole, 2.5 cm from the hilar vessels. The perirenal fat over the tumor is freely mobile, without gross evidence of involvement. Representative tumor was taken for [REDACTED] cytogenetics, and tumor bank, and representative normal kidney was sent for [REDACTED] IF, and tumor bank.

[page 3 of 4]
There is no adrenal gland present, and the remaining renal tissue is grossly unremarkable without additional lesions or other abnormalities. The renal pelvis is likewise grossly unremarkable, lined by light tan, trabecular mucosa without abnormality.

Micro A1: Vascular, ureteral margins, 3 frags, [REDACTED]

Micro A2: Mass and closest, inked, adipose tissue margin, 1 frag [REDACTED]

Micro A3: Mass, 1 frag, [REDACTED]

Micro A4: Mass and adjacent, uninvolved kidney, 2 frags [REDACTED]

Micro A5: Mass and adjacent renal vein, 1 frag [REDACTED]

Micro A6: Uninvolved kidney, 1 frag [REDACTED]

[REDACTED]

By his/her signature below, the senior physician certifies that he/she personally conducted a microscopic examination ("gross only" exam if so stated) of the described specimen(s) and rendered or confirmed the diagnosis(es) related thereto.

[REDACTED]

ADDENDUM

RENAL PATHOLOGY EVALUATION OF NON-NEOPLASTIC KIDNEY PARENCHYMA

[page 4 of 4]
RIGHT KIDNEY, NEPHRECTOMY

MILD ARTERIAL AND ARTERIOLAR SCLEROSIS WITH HYALINOSIS (SEE NOTE)

Note:

The changes seen in the kidney parenchyma are mild and probably age-related.

MICROSCOPIC DESCRIPTION:

The section examined by light microscopy consists of kidney cortex and medulla.

There are 269 glomeruli present in the sample, of which 1 (0.4%) is globally obsolescent (sclerosed). The preserved glomeruli show normal cellularity and reveal no significant pathological changes. On PAS and Jones methenamine silver stains, the glomerular basement membranes appear of normal thickness; "spikes", craters, or double contours are not evident. Tubules and interstitium are well preserved, with no significant tubular atrophy or interstitial fibrosis, as evidenced on the trichrome stain (AFOG). Arteries show mild subintimal sclerosis, and arterioles show mild medial sclerosis with focal segmental hyaline degeneration.

Source: NCI Genomic Data Commons file eb32c706-4358-4399-9bfd-115631b804bc (TCGA-KN-8424.60B044B4-9F1A-43DB-B421-325471A068F8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).